CCDI case PBCAUK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d4d783da-db32-4421-93c5-4c5aa2cdb24e

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: ICD-O-3 morphology code: 9161/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 16.2 years (5,902 days).

Biospecimens (3 samples)
- Sample 0DMUXE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMUY1: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMUZ8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
